Somatic mutation profile of tumor specimen TCGA-26-6173-01A (aliquot TCGA-26-6173-01A-11D-1845-08) from TCGA case TCGA-26-6173, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-26-6173-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c300c0-9ecc-4813-ac1f-3b7294a1c8ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-6173-10A (Blood Derived Normal), aliquot TCGA-26-6173-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea9a935d-5d90-4ff9-ac1c-eec243a4aafa

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Splice Region 2, Intron 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1198605516, COSV61355422; called by muse, mutect2, varscan2
- ATXN2L | c.2917A>T p.T973S | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV57364862; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs746043904; called by mutect2, varscan2
- C14orf39 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100407842, COSV58779289; called by muse, mutect2, varscan2
- CAP2 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57729606; called by muse, mutect2, varscan2
- CMYA5 | c.5291G>T p.G1764V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV71404049; called by muse, mutect2, varscan2
- DAGLB | c.1888C>T p.L630F | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV51702071; called by muse, mutect2, varscan2
- DMBT1 | c.4874C>G p.S1625C (on ENST00000338354 / NM_001377530.1; = p.S868C on NM_004406.3) | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs756284043, COSV57533543; called by muse, mutect2, varscan2
- EP300 | c.3602G>A p.C1201Y | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54325551, COSV54336199; called by muse, mutect2, varscan2
- FAM81B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs202064996, COSV51980413, COSV51987400; called by muse, mutect2, varscan2
- IRX1 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57357837; called by muse, mutect2, varscan2
- ITGA9 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53235510, COSV99292303; called by muse, mutect2, varscan2
- MMP3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147533686; called by muse, mutect2, varscan2
- MYH8 | c.3055A>T p.K1019* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | catalogued as COSV67959408; called by muse, mutect2, varscan2
- NDUFA3 | c.162A>C p.P54= | Splice Region (SNP) | VAF 18/72 reads (25%) | catalogued as COSV52926917; called by muse, mutect2
- NLGN1 | c.645C>T p.L215= | Splice Region (SNP) | VAF 16/68 reads (24%) | catalogued as rs779083189, COSV64323108; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOM1 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs758863542, COSV51978733; called by muse, mutect2, varscan2
- NTSR1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as rs895974712, COSV65137974, COSV65138411; called by muse, mutect2, varscan2
- OR10R2 | c.220del p.S74Afs*64 | Frame Shift Del (DEL) | VAF 29/196 reads (15%) | catalogued as rs1157565685; called by mutect2, pindel, varscan2
- OR8K3 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs766060464, COSV57130713, COSV57130774; called by muse, mutect2, varscan2
- ROS1 | c.6135+1G>A p.X2045_splice | Splice Site (SNP) | VAF 44/149 reads (30%) | catalogued as rs759495322, COSV63851057; called by muse, mutect2, varscan2
- SIPA1 | c.2558A>C p.N853T | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); catalogued as rs753050344, COSV58013776; called by muse, mutect2, varscan2
- XAB2 | c.1577T>C p.M526T | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs374151176; called by muse, mutect2, varscan2
- ZFP36L1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.039); catalogued as COSV60544244; called by muse, mutect2, varscan2
- ZNF497 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.121); catalogued as COSV54049654; called by muse, mutect2, varscan2
- ARHGAP15 | c.1023C>T p.D341= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs138120208; called by muse, mutect2, varscan2
- CACNA1B | c.717C>T p.I239= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53112589, COSV99496139; called by muse, mutect2, varscan2
- CLNK | c.735T>C p.S245= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57010633; called by muse, mutect2, varscan2
- CYP11B1 | c.288C>T p.D96= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs5284; ClinVar: likely benign; called by muse, mutect2, varscan2
- GABRA6 | c.1230C>A p.A410= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV50877451; called by muse, mutect2, varscan2
- LCE1C | c.321C>T p.G107= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as rs551622346, COSV64218139, COSV64218259; called by muse, mutect2, varscan2
- MANSC1 | c.1203C>T p.L401= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs757970869, COSV67110613; called by muse, mutect2, varscan2
- MS4A3 | c.72G>A p.A24= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs763316046, COSV53934724; called by muse, mutect2, varscan2
- EPHA8 | c.1315+18G>A | Intron (SNP) | VAF 22/50 reads (44%) | catalogued as rs199679973, COSV51273871; called by muse, mutect2, varscan2
